Somatic mutation profile of tumor specimen TCGA-VD-A8KF-01A (aliquot TCGA-VD-A8KF-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KF, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.6 years (25,066 days).
Specimen TCGA-VD-A8KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8bb3f0d-ceab-4ae1-82bc-37c54abe03a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KF-10A (Blood Derived Normal), aliquot TCGA-VD-A8KF-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cec59e93-8ffe-4c0a-b89a-952bd093c6c1

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRRC15 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMD15 | c.1960C>A p.Q654K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SPRR2A | c.211_215del p.S71Vfs*13 | Frame Shift Del (DEL) | VAF 33/80 reads (41%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1209G>T p.G403= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- PCDH9 | c.2490C>T p.I830= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as COSV60530621; called by muse, mutect2, varscan2
